Somatic mutation profile of tumor specimen 0DHE08 from CCDI case PBBTKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar soft part sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 14.3 years (5,228 days).
Specimen 0DHE08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ca73f58-fcfd-40eb-875c-b836494e8127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4b92864-bcb5-45d5-ba6a-e22742a3292f

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RFLNB | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 99/505 reads (20%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs1555543325; called by muse, mutect2, varscan2
- SETSIP | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 169/853 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs540986840; called by muse, varscan2
- CDC42BPA | c.4642G>A p.V1548I (on ENST00000334218 / NM_001366019.2; = p.V1535I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/566 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2
- NUP205 | c.4466A>C p.H1489P | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNTTIP2 | c.2068-74T>C | Intron (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- EREG | c.279-14G>A | Intron (SNP) | VAF 24/279 reads (9%) | catalogued as rs1268508146; called by muse, mutect2
